Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAIC, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-2G-AAIC-01A (Primary Tumor).

Department of Pathology

Direct dial

Mobile

Internal postal address

E-mail

Date

Concerning

Postal address

Street address

Summary pathology report

Right orchidectomy; seminoma; diameter 5.0 cm; lymphatic invasion present; no invasion of rete testis; no angio-invasion. Tumor confined to testis in available slides.

Date of procurement (= date of orchidectomy):

ICD O-3
Seminoma NOS 9061/3
Site: R Testis NOS
C62.9
JW 6/7/14

pathologist

professor of pathology

Source: NCI Genomic Data Commons file e1931e4a-9c0a-42db-a051-64b8e9646648 (TCGA-2G-AAIC-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).